Somatic mutation profile of tumor specimen 0DMKB3 from CCDI case PBCAGR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 7.8 years (2,835 days).
Specimen 0DMKB3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b612871-7c4b-45f3-a0f0-b23926cdb2cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKB2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24d35d4f-4ba0-4e13-bd3a-c7e630aae330

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Frame Shift Ins 1, 3'UTR 1, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARR3 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 54/870 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs773226154, COSV57203779; called by muse, mutect2
- CCDC88A | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 80/1096 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs745518858, COSV55057245; called by muse, mutect2
- DYSF | c.6130C>T p.R2044W | Missense Mutation (SNP) | VAF 277/777 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs185617318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.12056C>T p.A4019V | Missense Mutation (SNP) | VAF 127/946 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.038); catalogued as rs372573825, COSV64243294; called by muse, mutect2, varscan2
- GLI2 | c.3011G>A p.R1004H (on ENST00000361492 / NM_001374353.1; = p.R1021H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs749819734, COSV58053376; called by muse, mutect2, varscan2
- PDXDC1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 221/599 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs778783741, COSV55074014; called by muse, mutect2, varscan2
- UNC5B | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 105/620 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.756); catalogued as rs548022173; called by muse, mutect2, varscan2
- ZNF845 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1239350099, COSV72004794; called by muse, mutect2, varscan2
- CCDC168 | c.13996A>G p.T4666A | Missense Mutation (SNP) | VAF 183/796 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CD6 | c.809dup p.A271Rfs*2 | Frame Shift Ins (INS) | VAF 73/355 reads (21%) | called by mutect2, varscan2
- DUSP9 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZNF845 | c.1083C>T p.D361= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1180196074; called by muse, mutect2, varscan2
- CRELD1 | c.257+12C>A | Intron (SNP) | VAF 109/563 reads (19%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- MEIOC | c.2457+94C>G | Intron (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- NTM | c.*44C>T | 3'UTR (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
